Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A7GI, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A7GI-01A (Primary Tumor).

[page 1 of 3]
Diagnosis:

A: Left kidney, nephrectomy

- Renal cell carcinoma, chromophobe type, eosinophilic variant, tumor size 3.5 cm in greatest dimension, nuclear grade 2 (of 4), tumor confined to kidney, surgical margins free of tumor
- Renal vein, artery and ureter with no tumor seen
- Portion of adrenal gland with no tumor seen

B: Left adrenal gland, mass removal

- Adrenal myelolipoma, tumor size 14 cm in greatest dimension

Comment:

None.

Clinical History:

year-old male with left adrenal mass.

ICD-O-3
Carcinoma, renal cell
Chromophobe type 8317/3
Site @ Kidney NOS
C64.9
JWD 9/24/13

Gross Description:

Received are two appropriately labeled containers.

Container A:

Specimen fixation: formalin

Type of specimen: nephrectomy

Size and weight of specimen: 500 grams, 14.5 x 10.0 x 4.8 cm

Presence/absence of adrenal gland: questionably present, an area of yellow/orange discoloration is present in the perirenal adipose tissue, but not definitive for an adrenal gland

Tumor description: circumscribed, yellow/tan, soft, and partially encapsulated

Tumor size: 3.5 x 3.5 x 3.0 cm

Presence/absence of multicentricity: absent, one focus is identified

Confinement/Non-confinement to kidney: the tumor grossly appears to contain questionable areas of extracapsular extension into the surrounding fat

Extent of invasion:

Perirenal adipose tissue: questionably involved

[page 2 of 3]
Renal vein: tumor does not grossly involve
Ureter: tumor does not grossly involve

Surgical margins:

Perirenal adipose tissue: extends to within 0.8 cm of the closest black inked deep soft tissue margin
Renal vein: negative
Renal artery: negative
Ureter: negative

Description of kidney away from tumor: has a pink/tan, smooth, and grossly unremarkable cut surface, with distinct corticomedullary junctions; the cortex contains two linear incisional defects, containing suture material, one located on each pole

Lymph nodes (hilar): none

Tissue submitted for special investigations: none

Block Summary:

A1 - vascular and ureteral margins
A2 - tumor at closest approach to black ink
A3,A4 - tumor at area of questionable extracapsular extension
A5,A6 - additional representative tumor
A7 - additional representative normal kidney
A8 - representative section of area with adipose tissue containing an orange/yellow discoloration (possible portion of adrenal gland)

Container B is additionally labeled "left adrenal mass." It holds a 1010 gram, 14.2 x 13.2 x 7.0 cm ovoid, circumscribed, soft tan/gray mass, containing areas of disrupted surface. A 10.0 x 1.0 cm area contains an orange/yellow minimal amount of adherent portion of tissue, consistent with adrenal gland. Sectioning reveals a soft, yellow/tan, focally hemorrhagic and focally necrotic cut surface. This mass diffusely abuts the blue inked surgical margin. The area underlying the yellow/orange surface has a red/brown, hemorrhagic cut surface, with a small, approximately 0.5 x 0.1 cm rim of orange yellow tissue, consistent with adrenal gland.

B1-B5 - representative sections

B6 - sections of area containing yellow/orange possible adrenal gland

[page 3 of 3]
Light Microscopy:

Light microscopic examination is performed by Dr.

Specimen A:

Histologic tumor type/subtype: renal cell carcinoma, chromophobe type, eosinophilic variant

Histologic grade (if applicable): 2 (of 4)

Tumor size (greatest dimension): 3.5 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: negative

Renal vein: negative

Ureter: negative

Blood vascular: negative

Lymphovascular: negative

Histologic assessment of surgical margins:

Perirenal adipose tissue: free of tumor

Renal vein: free of tumor

Renal artery: free of tumor

Ureter: free of tumor

Adrenal gland: no tumor seen. Separately submitted specimen B shows a 14 cm myelolipoma of the adrenal gland.

Lymph nodes: not identified

Other significant findings: none

Source: NCI Genomic Data Commons file 46fd864c-70f7-4f1f-b28c-30f361afcd55 (TCGA-UW-A7GI.EEB0E26D-3BF2-4D38-8D94-4251A03344D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).